Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A94T, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A94T-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

1 - "Celiac trunk lymph node":

. Absence of neoplastic involvement: (0/1)

2 - "Product of total gastrectomy":

. Ulcerated invasive poorly differentiated adenocarcinoma diffuse pattern of Laurén

. Tumor size: 5.0 x 4.0 x 1.7cm.

. Depth of infiltration: until the adjacent adipose tissue

. Blood vascular invasion: not detected

. Lymphatic vascular invasion: present

. Perineural invasion: not detected

. Adjacent mucosa: inactive chronic discrete gastritis

. Distal surgical margins uninvolved by neoplasia

. Proximal surgical margin (frozen) involved.

. Metastasis in 9 of 33 dissected lymph nodes with capsular transposition (9/33).

3 - "Expansion of esophageal margin":

. Involved by neoplasia.

4 - "Esophageal margin (separately)":

. Absence of neoplastic involvement.

ICD-O-3

Adenocarcinoma, diffuse
type 8145/3

Site: Cardia NOS C16.0

JS 3/13/14

Site/AA Discrepancy		☒

Source: NCI Genomic Data Commons file 21d72f56-e6e4-4e4b-b1c1-7c3066b305d4 (TCGA-VQ-A94T.AC1D440D-E4EA-4B0B-A392-9AB80E7BDE42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).